Somatic mutation profile of tumor specimen 0DS06L from CCDI case PBCFKW, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 8.0 years (2,907 days).
Specimen 0DS06L: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f445624e-4085-4007-a78b-8ec96151520d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DRY84 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/df4c03f0-4aee-4524-a3b9-65efbfebe75c

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, Splice Site 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DDX10 | c.248G>T p.G83V | Missense Mutation (SNP) | VAF 34/550 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); catalogued as COSV59439107; called by muse, mutect2
- POMK | c.137G>A p.R46Q | Missense Mutation (SNP) | VAF 85/253 reads (34%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs1463768524, COSV58858478; called by muse, varscan2
- ST3GAL4 | c.16+1G>A p.X6_splice | Splice Site (SNP) | VAF 84/272 reads (31%) | catalogued as rs1434841058; called by muse, mutect2, varscan2
- HMGB1 | c.*85T>C | 3'UTR (SNP) | VAF 14/212 reads (7%) | catalogued as COSV100360835; called by muse, mutect2
